Surgical pathology report (de-identified scan), TCGA case TCGA-B2-3923, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site Christiana Healthcare, specimen TCGA-B2-3923-01A (Primary Tumor).

[page 1 of 2]
SPECIMEN

Right kidney

CLINICAL NOTES

Renal mass

GROSS DESCRIPTION

Received fresh for tissue procurement labeled "right kidney" is a 1,005 gram, 20 x 11 x 8.5 cm right kidney with attached, probe-patent, 7 cm ureter averaging 0.5 cm in diameter. An abundant amount of perirenal adipose tissue is present which is received predominantly torn from the kidney proper. Multiple stapled vessels are at the hilum. No adrenal gland appears to be present. The capsule is smooth to slightly scabrous delicate tan-pink and strips with relative ease from the underlying cortical surface. On sectioning, there is a moderately well circumscribed, calcified necrosed 11.8 x 10.5 x 8.5 cm golden brown tumor mass which occupies the inferior pole. The tumor appears to extend up to, but not through the delicate capsular surface. The aforementioned calcified region of the specimen appears to be predominantly central. The renal pelvis is flat, glistening tan-white. The uninvolved renal parenchyma is uniform red-brown with a moderately well defined corticomedullary junction and a maximal cortical thickness of 1.2 cm. No additional mass lesions or abnormalities are identified. Representative sections are submitted in nine blocks as labeled. RS-9.

BLOCK SUMMARY: 1 - Vascular and ureteral margins; 2-5 - tumor full thickness to inked capsular surface; 6 - tumor to normal parenchyma; 7 - renal pelvis; 8,9 - random normal parenchyma.

[page 2 of 2]
MICROSCOPIC DESCRIPTION

Sections show a mass lesion composed of nests or broad of large polygonal cells with abundant cytoplasm, perinuclear halos, and distinct cell borders. Nuclei are bland, and calcifications are easily identifiable. Cytoplasm stains positively

colloidal iron. Findings are consistent with renal cell carcinoma, chromophobe type.

Histologic type: Renal cell carcinoma, chromophobe type
Histologic grade (Fuhrman Nuclear Grade): 2
Primary tumor (pT): pT2 (size 11.8 cm; confined to kidney)
Margins of resection: Negative
Regional lymph nodes (pN): None submitted
Adrenal gland: Not submitted
Vascular invasion: Negative
Non-neoplastic kidney: Unremarkable

4, 18

DIAGNOSIS

Kidney, right, nephrectomy:

Renal cell carcinoma, chromophobe type.

Size: 11.8 cm in greatest dimension (inferior pole).

Margins: negative.

Vascular invasion: not identified.

--- End Of Report ---

Source: NCI Genomic Data Commons file de9fe615-f0ab-4172-9ffa-0a33e34f7df9 (TCGA-B2-3923.DE7A1EAD-E27F-44F8-A903-F9E308EFFBFF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).